CGCI case HTMCP-01-20-00272 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7189da6-4ba3-485d-9412-a66058bfa18f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 47.8 years (17,461 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,623 days (4.4 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Adrenal gland, NOS / Soft tissue / Nasopharynx / Lung, NOS / Small intestine.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 2.8 cm.
   Pathology details: Lymph node involved site: Parotid.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 25 days; Disease response: With Tumor.
- Days to follow up: 399 days (1.1 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 1,623 days (4.4 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Follow-up contacts recording only the day: day 0, day 12.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus: Positive.
- Lactate Dehydrogenase 644 [Blood test normal range upper: 610].
- Epstein-Barr Virus (ISH): Positive.

Other clinical attributes
- Day 0: Comorbidities: Shingles.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: Weight: 74.03 kg; Height: 165.1 cm; BMI: 27.2; CD4 count: 241; Haart treatment indicator: No; HIV viral load: 87799.
- Day 0: Risk factors: Shingles.
- Day 12: Comorbidities: HIV/AIDS.
- Day 12: Risk factors: HIV/AIDS.
- Day 25: Nadir CD4 count: 241.

Biospecimens (3 samples)
- Sample HTMCP-01-20-00272-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-20-00272-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-20-00272-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lost to follow-up: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No; History relevant infectious diagnosis: shingles.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Adrenal; Submitted tumor site: Soft Tissue (muscle  ligaments  subcutaneous); Submitted tumor site: Nasopharynx; Submitted tumor site: Lung; Submitted tumor site: Other Extranodal Site.
- Primary pathology: Extranodal involvment other: Other sites: thoracic, iliac; Extranodal site involvement: 6; Method initial path diagnosis: Biopsy (all types).
- Tests performed: LDH level: 644.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-20-00272-01A-01E-12273:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-20-00272-01A-01S-12273:
- % tumour top: 70
- % tumour bottom: 70
